Gene-level copy-number profile of tumor specimen TARGET-20-PASGZS-04A from TARGET case TARGET-20-PASGZS, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.2 years (446 days).
Specimen TARGET-20-PASGZS-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.72f23575-0bd7-522f-915f-1e395513d7cd.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PASGZS-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 388 have no estimate.
https://portal.gdc.cancer.gov/files/9f52ed97-e698-403a-b7e5-a9783ae11f20

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 532; copy number 1: 42; copy number 2: 58,204; copy number 3: 1,457.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:241,881,363–242,078,722, 1 gene (within-gene range 0–2): LINC01237.
- chr2:242,001,209–242,160,153, 8 genes: AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2, LINC01881, CICP10, SEPTIN14P2.
- chr12:9,480,608–9,576,275, 2 genes (within-gene range 0–2): AC092821.1, AC092821.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 42. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
